CPTAC case 14BR008 — Breast — Ductal and Lobular Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/e2549d98-1b68-4c4d-b7f6-311fdd05b260

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Infiltrating lobular carcinoma, NOS: ICD-O-3 morphology code: 8520/3; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 66.0 years (24,089 days); AJCC pathologic stage: Stage IIIA; Prior malignancy: no.

Biospecimens (3 samples)
- Sample 5d7892a4-966e-44e4-b4d1-83173f: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples 99df02e0-56b3-4b00-80b7-ea58ce, ca14c6dd-2069-4bc5-b1f2-6f2297 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
